Somatic mutation profile of tumor specimen TCGA-AC-A4ZE-01A (aliquot TCGA-AC-A4ZE-01A-11D-A41F-09) from TCGA case TCGA-AC-A4ZE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.7 years (23,284 days).
Specimen TCGA-AC-A4ZE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 215e19b1-2444-4e32-8bc3-182d623c7352.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A4ZE-10B (Blood Derived Normal), aliquot TCGA-AC-A4ZE-10B-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3cdd869-c63f-4623-8277-4a0ae2141556

The open-access MAF lists 50 somatic variants for this specimen: 42 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.49-2A>G p.X17_splice | Splice Site (SNP) | VAF 90/129 reads (70%) | catalogued as rs1060501226, CS071157, CS991340, COSV99932350; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXA1 | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 22/89 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1329067081, COSV51643334, COSV51643414, COSV51644409; called by muse, mutect2, varscan2
- AHNAK2 | c.13253C>T p.T4418M | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs372841773; called by muse, mutect2, varscan2
- CDCA4 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100288229; called by muse, mutect2
- COL12A1 | c.8668G>T p.G2890* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100486021, COSV100486265; called by muse, mutect2, varscan2
- COL17A1 | c.1089G>T p.M363I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100793250; called by muse, mutect2, varscan2
- DENND3 | c.3382C>T p.R1128W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1323176375, COSV99371019, COSV99371306; called by muse, mutect2, varscan2
- DFFB | c.884C>A p.T295N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100220821; called by muse, mutect2, varscan2
- FRMD3 | c.1753G>T p.G585W | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV100170976, COSV58469836; called by muse, mutect2, varscan2
- FRMPD1 | c.4328G>T p.G1443V | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV100899597; called by muse, mutect2, varscan2
- GBF1 | c.4943T>A p.I1648N (on ENST00000369983 / NM_001377137.1; = p.I1647N on NM_004193.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100890575; called by muse, mutect2, varscan2
- GBP5 | c.164T>C p.M55T | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1214587222, COSV100600136, COSV58593333; called by muse, mutect2, varscan2
- HPDL | c.131_150del p.Q44Rfs*145 | Frame Shift Del (DEL) | VAF 35/127 reads (28%) | catalogued as rs1450748720; called by mutect2, pindel, varscan2
- IRAG1 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as COSV101351403; called by muse, mutect2, varscan2
- KCNK7 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs753915954, COSV100442301; called by muse, varscan2
- LRP12 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52630304; called by muse, mutect2, varscan2
- LRP1B | c.4981C>T p.R1661C | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs150231464, COSV101258278; called by muse, mutect2, varscan2
- MAP3K4 | c.4109C>G p.A1370G | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815549, COSV62339425; called by muse, mutect2, varscan2
- MARCHF8 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165929; called by muse, mutect2, varscan2
- MCOLN1 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99654111; called by muse, mutect2, varscan2
- MUC4 | c.13957C>T p.R4653C (on ENST00000463781 / NM_018406.7; = p.R417C on NM_004532.6) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as rs767067185, COSV100205572; called by muse, mutect2, varscan2
- NR0B1 | c.618C>A p.H206Q | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100973558; called by muse, mutect2, varscan2
- NR1I2 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100561637; called by muse, mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- PCDH8 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs751398851, COSV100131908; called by muse, varscan2
- POLR2E | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs939539104, COSV99297646; called by muse, mutect2, varscan2
- PPP1R36 | c.533+1G>A p.X178_splice | Splice Site (SNP) | VAF 46/121 reads (38%) | catalogued as rs781096538, COSV100072949; called by muse, mutect2, varscan2
- RBM12 | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100467811; called by muse, mutect2, varscan2
- RNASE13 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs953362983, COSV58794582; called by muse, mutect2
- SCN10A | c.767G>T p.C256F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV101479474; called by mutect2, varscan2
- SCN5A | c.3584G>A p.R1195H (on ENST00000333535 / NM_198056.3; = p.R1194H on NM_000335.5) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199473596, CM098020, COSV100350649, COSV61124717; ClinVar: not provided; called by muse, mutect2, varscan2
- SOX6 | c.1878T>A p.N626K (on ENST00000528429 / NM_001145819.2; = p.N599K on NM_017508.3) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100322687; called by muse, mutect2, varscan2
- STK17B | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99826198; called by muse, mutect2, varscan2
- SUN1 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100568751; called by muse, mutect2, varscan2
- TEX15 | c.1450G>A p.A484T (on ENST00000256246; = p.A867T on NM_001350162.2) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs1379221141, COSV99821790; called by muse, mutect2, varscan2
- UPRT | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); catalogued as COSV100974516, COSV64912460; called by muse, mutect2, varscan2
- WDR49 | c.646G>C p.V216L (on ENST00000308378 / NM_001366158.1; = p.V557L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100393350; called by muse, mutect2, varscan2
- ZMIZ1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV57892061; called by muse, mutect2, varscan2
- ZNF341 | c.1967C>T p.T656M (on ENST00000375200 / NM_001282935.1; = p.T649M on NM_032819.4) | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs763451931, COSV100677937, COSV61010731; called by muse, mutect2, varscan2
- ARHGEF15 | c.197dup p.A67Sfs*16 | Frame Shift Ins (INS) | VAF 18/36 reads (50%) | called by pindel, varscan2
- FPR3 | c.270dup p.W91Mfs*9 | Frame Shift Ins (INS) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- RBP3 | c.1813G>T p.A605S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FKBP6 | c.51C>T p.P17= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs1563308143; called by muse, mutect2
- HOXA5 | c.30C>T p.C10= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV56072557; called by muse, mutect2
- PCDHB11 | c.1788G>A p.S596= | Silent (SNP) | VAF 18/274 reads (7%) | catalogued as COSV61312040; called by muse, mutect2
- PCDHB2 | c.1041G>A p.P347= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV50563950; called by muse, mutect2, varscan2
- PRKDC | c.1047C>T p.I349= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as rs762669277, COSV100041695; called by muse, mutect2, varscan2
- SORBS2 | c.537G>C p.P179= (on ENST00000284776 / NM_021069.5; = p.P225= on NM_003603.6) | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV99511848; called by muse, mutect2, varscan2
- ZAN | c.7324C>T p.L2442= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as COSV100769959; called by muse, mutect2, varscan2
- TTN | c.10360+1606G>A | Intron (SNP) | VAF 15/43 reads (35%) | catalogued as COSV60101255, COSV60251234; called by muse, mutect2, varscan2
